Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5751, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5751-01A (Primary Tumor).

**Diagnosis**

1. Tumor-free lymph node.
2. Tumor-free fatty tissue.
3. Tumor-free lymph node.

TCGA-CH-5751

4. Prostatectomy preparation with bilateral extensive poorly differentiated adenocarcinoma, with perineural growth, invasion of lymph and blood vessels, infiltration of yellow, blue and green labeled preparation margins close to the base, bilateral infiltration of the seminal vesicles and the wall of the bladder with a lymph node metastasis.

Tumor is classification: pT4 pN1 L1 V1, G4; total score 5+5 = 10, corresponding to stage IV.

Remark

The preparation margins on both sides close to the base are extensively infiltrated with tumor.

Source: NCI Genomic Data Commons file 61ee214a-71ae-4223-86e6-36b9e9dc5575 (TCGA-CH-5751.C4240096-B982-4B8A-B871-677A94CFD6CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).